TCGA case TCGA-VQ-A928 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/43b7a790-35a2-4786-b375-c3847d2aec62

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Brazil; Age at index: 49 years; Vital status: Dead; Days to death: 174 days; Cause of death: Cancer Related.

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C16.2; Tissue or organ of origin: Body of stomach; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 49.4 years (18,058 days); Year of diagnosis: 2010; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N3; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 32; Lymph nodes tested: 81.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 98 days; Days to treatment end: 138 days; Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Papillary adenocarcinoma, NOS), site: Liver. Age at diagnosis: 49.8 years (18,206 days); Days to diagnosis: 148 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (2 entries)
- Day 148 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 148 days; Evidence of progression type: Convincing Image Source.
- Days to follow up: 174 days; Disease response: With Tumor.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VQ-A928-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 130 mg.
  Slide TCGA-VQ-A928-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 3.
- Sample TCGA-VQ-A928-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VQ-A928-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Intestinal Adenocarcinoma, Papillary Type; Cause of death: Stomach Cancer; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Anatomic organ subdivision: Fundus/Body; Lymph nodes examined: Yes; Tumor sample procurement country: Sao Paulo; Cancer procurement city: Barretos; History reflux disease indicator: No; Antireflux treatment: No; History barretts esophageal indicator: No; History hpylori infection indicator: No.
- Drug treatment: Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 174 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 174 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 148 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VQ-A928-01A-11D-A40Z-01): tumor purity 0.56, ploidy 2.09, whole-genome doublings 0.
